Somatic mutation profile of tumor specimen C3N-00155-04 (aliquot CPT0104820009) from CPTAC case C3N-00155, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage I; FIGO stage: Stage I; Tumor grade: G1; Age at diagnosis: 57.3 years (20,946 days).
Specimen C3N-00155-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) db19e214-9936-484a-8729-3173adf7c9ca.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00155-31 (Blood Derived Normal), aliquot CPT0110000002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/638dcdc8-1162-4f36-96e1-73cc9f63f29b

The open-access MAF lists 228 somatic variants for this specimen: 153 protein-altering or splice-affecting, 46 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 111, Silent 46, Frame Shift Del 23, Intron 14, Nonsense Mutation 7, Frame Shift Ins 6, RNA 5, 3'UTR 4, In Frame Del 3, 5'Flank 3, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 62/378 reads (16%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- B3GALT6 | c.588del p.R197Afs*81 | Frame Shift Del (DEL) | VAF 18/121 reads (15%) | catalogued as rs533071750, COSV55420617; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NOTCH2 | c.6909del p.I2304Lfs*2 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | catalogued as rs771237928; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PCDH19 | c.1091del p.P364Rfs*4 | Frame Shift Del (DEL) | VAF 34/196 reads (17%) | catalogued as rs758946412, CD134966; ClinVar: pathogenic; called by mutect2, varscan2
- PIK3CA | c.1030G>A p.V344M | Missense Mutation (SNP) | VAF 17/88 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1057519942, COSV55881590; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3129G>A p.M1043I | Missense Mutation (SNP) | VAF 9/84 reads (11%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.026); catalogued as rs121913283, CM126698, COSV55873376, COSV55878974, COSV55898229; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.277C>T p.H93Y | Missense Mutation (SNP) | VAF 37/313 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM983500, COSV64289544, COSV64299563; called by muse, mutect2, varscan2
- PTEN | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 55/262 reads (21%) | catalogued as rs786202840, COSV64292512, COSV64297236; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACE | c.2875G>A p.A959T | Missense Mutation (SNP) | VAF 94/454 reads (21%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.871); catalogued as rs756159839; called by muse, mutect2, varscan2
- ALOXE3 | c.1486C>T p.R496W | Missense Mutation (SNP) | VAF 21/570 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs867780319, COSV59075685; ClinVar: uncertain significance; called by muse, mutect2
- ANAPC2 | c.1957C>T p.R653C | Missense Mutation (SNP) | VAF 40/212 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs759968483; called by muse, mutect2, varscan2
- ATG4C | c.118_120del p.P40del | In Frame Del (DEL) | VAF 7/70 reads (10%) | catalogued as rs1047505101; called by mutect2, pindel
- BHLHE22 | c.464G>A p.R155H | Missense Mutation (SNP) | VAF 17/209 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100417644; called by muse, mutect2
- CCDC8 | c.890del p.G297Efs*12 | Frame Shift Del (DEL) | VAF 12/78 reads (15%) | catalogued as rs1450099223; called by mutect2, pindel, varscan2
- CCNI2 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 35/237 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.65); catalogued as rs373566408; called by muse, mutect2, varscan2
- CDC5L | c.577G>A p.A193T | Missense Mutation (SNP) | VAF 43/161 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65175912; called by muse, mutect2, varscan2
- CEBPZ | c.1428del p.D477Mfs*11 | Frame Shift Del (DEL) | VAF 30/137 reads (22%) | catalogued as rs763090473; called by mutect2, varscan2
- CELSR3 | c.2062T>C p.Y688H | Missense Mutation (SNP) | VAF 15/204 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99372860; called by muse, mutect2
- CERT1 | c.26C>T p.P9L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.036); catalogued as rs768787922; called by muse, mutect2, varscan2
- CHD8 | c.4597C>T p.R1533C (on ENST00000646647 / NM_001170629.2; = p.R1254C on NM_020920.4) | Missense Mutation (SNP) | VAF 20/189 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs773611059; called by muse, mutect2, varscan2
- CMYA5 | c.9500G>A p.R3167Q | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.022); catalogued as rs1368355148; called by muse, mutect2, varscan2
- CNTNAP1 | c.3739G>A p.E1247K | Missense Mutation (SNP) | VAF 64/413 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs747441144, COSV52854264; called by muse, mutect2, varscan2
- COL18A1 | c.4826G>A p.R1609Q (on ENST00000359759 / NM_130444.3; = p.R1374Q on NM_030582.4) | Missense Mutation (SNP) | VAF 24/358 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.673); catalogued as rs756649129, COSV60592060; called by muse, mutect2
- CRACR2A | c.19del p.R7Gfs*2 | Frame Shift Del (DEL) | VAF 31/245 reads (13%) | catalogued as rs753466796; called by mutect2, pindel
- CSMD3 | c.8109A>T p.E2703D | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.039); catalogued as rs765423386; called by muse, mutect2, varscan2
- DCHS2 | c.1306G>A p.V436M | Missense Mutation (SNP) | VAF 28/172 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100251246, COSV59724400; called by muse, mutect2, varscan2
- DCT | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 14/199 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.412); catalogued as COSV65468505; called by muse, mutect2
- DSPP | c.3571G>A p.D1191N | Missense Mutation (SNP) | VAF 153/915 reads (17%) | SIFT tolerated, low confidence (0.62); PolyPhen possibly damaging (0.728); catalogued as rs749131856; called by muse, varscan2
- E2F1 | c.631C>T p.R211* | Nonsense Mutation (SNP) | VAF 47/300 reads (16%) | catalogued as rs1223127537, COSV55774398; called by muse, mutect2, varscan2
- EBF1 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 44/241 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs566667549; called by muse, mutect2, varscan2
- ERCC6 | c.2144del p.G715Dfs*24 | Frame Shift Del (DEL) | VAF 27/178 reads (15%) | catalogued as CD982622; called by mutect2, pindel, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 44/296 reads (15%) | catalogued as rs775950025; called by mutect2, varscan2
- GCNA | c.1760G>A p.R587Q | Missense Mutation (SNP) | VAF 35/208 reads (17%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); catalogued as rs754484042, COSV65461912; called by muse, mutect2, varscan2
- GIPC1 | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 16/308 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen probably damaging (0.939); catalogued as rs200690262, COSV61775234; called by muse, mutect2
- GNAO1 | c.299G>T p.R100I | Missense Mutation (SNP) | VAF 30/108 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.474); catalogued as COSV104390534; called by muse, mutect2, varscan2
- GRB10 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 41/256 reads (16%) | SIFT tolerated (0.74); PolyPhen benign (0.02); catalogued as COSV60013513; called by muse, mutect2, varscan2
- GRM5 | c.3457G>A p.A1153T (on ENST00000305447 / NM_001143831.2; = p.A1121T on NM_000842.4) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); catalogued as rs1417987251; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 22/62 reads (35%) | catalogued as rs754199513; called by mutect2, varscan2
- GYS2 | c.1739G>A p.R580H | Missense Mutation (SNP) | VAF 43/283 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762150312, COSV53920433; called by muse, mutect2, varscan2
- HDAC4 | c.2726C>T p.A909V | Missense Mutation (SNP) | VAF 50/229 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.703); catalogued as rs868676793, COSV61859359; called by muse, mutect2, varscan2
- HECW1 | c.2303C>T p.P768L | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as rs1289082524, COSV101222945; called by muse, mutect2, varscan2
- IFFO2 | c.1402G>A p.V468M | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs755054349; called by muse, mutect2, varscan2
- INPPL1 | c.3466del p.R1156Gfs*46 | Frame Shift Del (DEL) | VAF 12/91 reads (13%) | catalogued as rs760925109; called by mutect2, pindel
- KCNV2 | c.200G>T p.W67L | Missense Mutation (SNP) | VAF 78/419 reads (19%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV101172502; called by muse, mutect2, varscan2
- LANCL3 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 73/474 reads (15%) | SIFT tolerated (0.05); PolyPhen benign (0.178); catalogued as COSV66130054; called by muse, mutect2, varscan2
- LMCD1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 34/222 reads (15%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.631); catalogued as rs768404180, COSV50088367; called by muse, mutect2, varscan2
- LPIN1 | c.2198C>T p.T733M | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1372423134; called by muse, mutect2
- LRP1B | c.5041G>A p.D1681N | Missense Mutation (SNP) | VAF 28/189 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as rs188652809, COSV67217355, COSV67278039; called by muse, mutect2, varscan2
- LRRC4B | c.677C>T p.T226M | Missense Mutation (SNP) | VAF 47/266 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.842); catalogued as rs757845731, COSV65349690; called by muse, mutect2, varscan2
- LRRN4 | c.1177G>A p.A393T | Missense Mutation (SNP) | VAF 55/230 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1364676614, COSV66645201; called by muse, mutect2, varscan2
- MARVELD3 | c.830G>A p.S277N | Missense Mutation (SNP) | VAF 49/272 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); catalogued as rs1391606932; called by muse, mutect2, varscan2
- MBOAT2 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs756373257, COSV60007885; called by muse, mutect2, varscan2
- MCAT | c.986C>A p.T329K | Missense Mutation (SNP) | VAF 74/354 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV51793275, COSV51793943; called by muse, mutect2, varscan2
- MGAM2 | c.4940C>A p.S1647* | Nonsense Mutation (SNP) | VAF 26/134 reads (19%) | catalogued as rs989085163; called by muse, varscan2
- MLLT6 | c.2204G>A p.R735Q | Missense Mutation (SNP) | VAF 68/360 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.2); catalogued as rs965801617; called by muse, mutect2, varscan2
- MTOR | c.7412C>T p.T2471M | Missense Mutation (SNP) | VAF 20/414 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1228569453, COSV63879176; called by muse, mutect2
- N4BP2 | c.4111C>G p.L1371V | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.311); catalogued as rs1008953158; called by muse, mutect2, varscan2
- NEURL4 | c.2548G>A p.G850S | Missense Mutation (SNP) | VAF 18/259 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1168735365; called by muse, mutect2
- OPRD1 | c.1040G>A p.R347H | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as rs753737057; called by muse, mutect2
- OTOG | c.4172G>A p.G1391D | Missense Mutation (SNP) | VAF 26/135 reads (19%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.627); catalogued as rs1261501532; called by muse, mutect2
- PKD1 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 79/420 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as rs377303753; called by muse, mutect2, varscan2
- PLD4 | c.1055dup p.R353Efs*130 | Frame Shift Ins (INS) | VAF 8/61 reads (13%) | catalogued as rs778485913; called by mutect2, pindel, varscan2
- PLXNA1 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 47/258 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.304); catalogued as rs762279605, COSV99303664; called by muse, mutect2, varscan2
- PLXNA2 | c.3766G>A p.V1256I | Missense Mutation (SNP) | VAF 101/540 reads (19%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.902); catalogued as rs775088776; called by muse, mutect2, varscan2
- RFX1 | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 45/242 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); catalogued as COSV99586473; called by muse, mutect2, varscan2
- RNF223 | c.694del p.R232Gfs*15 | Frame Shift Del (DEL) | VAF 34/168 reads (20%) | catalogued as rs771408178, COSV69251216; called by mutect2, varscan2
- ROBO1 | c.2085G>C p.W695C | Missense Mutation (SNP) | VAF 21/144 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101459219; called by muse, mutect2, varscan2
- RS1 | c.257C>A p.P86Q | Missense Mutation (SNP) | VAF 100/546 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.018); catalogued as COSV101183782, COSV66107403; called by muse, mutect2, varscan2
- SCARF2 | c.2174C>T p.T725M | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.029); catalogued as rs1221991531; called by muse, mutect2
- SERPINB9 | c.637C>T p.R213C | Missense Mutation (SNP) | VAF 59/379 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as rs774568244; called by muse, mutect2, varscan2
- SLC26A7 | c.879-2A>G p.X293_splice | Splice Site (SNP) | VAF 16/104 reads (15%) | catalogued as rs1242902764; called by mutect2, varscan2
- SLC35G2 | c.192del p.R66Efs*18 | Frame Shift Del (DEL) | VAF 18/108 reads (17%) | catalogued as rs750825208; called by mutect2, varscan2
- SORBS2 | c.1949A>G p.H650R | Missense Mutation (SNP) | VAF 59/309 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.777); catalogued as rs562339021, COSV52994457; called by mutect2, varscan2
- SOX30 | c.811G>T p.A271S | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.043); catalogued as rs1344859282; called by muse, mutect2
- SPTBN2 | c.2389C>T p.R797* | Nonsense Mutation (SNP) | VAF 80/523 reads (15%) | catalogued as COSV59447762; called by muse, mutect2, varscan2
- SRRM2 | c.4945_4947del p.P1649del | In Frame Del (DEL) | VAF 35/247 reads (14%) | catalogued as rs775291380; called by mutect2, pindel, varscan2
- TAF4 | c.1465G>A p.A489T | Missense Mutation (SNP) | VAF 43/266 reads (16%) | SIFT tolerated (0.96); PolyPhen benign (0.001); catalogued as rs780891295; called by muse, mutect2, varscan2
- TEF | c.405C>A p.S135R | Missense Mutation (SNP) | VAF 51/251 reads (20%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs768212737; called by muse, mutect2, varscan2
- TGM6 | c.1576C>T p.R526W | Missense Mutation (SNP) | VAF 33/390 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs1275709205, COSV52480072; called by muse, mutect2
- TMEM151B | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 71/328 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.62); catalogued as rs1223766512; called by muse, mutect2, varscan2
- TRIM58 | c.145G>A p.G49S | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs1288965906; called by muse, mutect2
- TTBK1 | c.598C>T p.R200* | Nonsense Mutation (SNP) | VAF 74/490 reads (15%) | catalogued as COSV52489945; called by muse, mutect2, varscan2
- UBAP1L | c.599del p.P200Rfs*69 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs1001155036; called by mutect2, pindel, varscan2
- WASL | c.1263dup p.V422Sfs*31 | Frame Shift Ins (INS) | VAF 68/460 reads (15%) | catalogued as rs1158703313; called by mutect2, varscan2
- ZBTB7B | c.1088G>A p.R363H (on ENST00000292176; = p.R397H on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/234 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1370862836, COSV52692474; called by muse, mutect2, varscan2
- ZC3H12C | c.2461C>T p.R821W | Missense Mutation (SNP) | VAF 71/360 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.965); catalogued as rs1015572213; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 12/81 reads (15%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZNF215 | c.1114del p.S372Vfs*5 | Frame Shift Del (DEL) | VAF 18/88 reads (20%) | catalogued as rs769655515; called by mutect2, pindel, varscan2
- ZNF324 | c.1198G>A p.A400T | Missense Mutation (SNP) | VAF 77/400 reads (19%) | SIFT tolerated (0.42); PolyPhen benign (0.352); catalogued as rs918914328, COSV52179535; called by muse, mutect2, varscan2
- ADH1B | c.613G>T p.G205C | Missense Mutation (SNP) | VAF 58/289 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AFAP1 | c.254C>T p.P85L | Missense Mutation (SNP) | VAF 22/319 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- ANKS1B | c.752A>G p.D251G | Missense Mutation (SNP) | VAF 10/166 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); called by muse, mutect2
- AQP9 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ARHGEF19 | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 40/652 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- ARHGEF3 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2
- ARID4B | c.3333del p.A1112Pfs*8 | Frame Shift Del (DEL) | VAF 14/92 reads (15%) | called by mutect2, pindel, varscan2
- C14orf132 | c.304A>G p.N102D (on ENST00000553782 / NM_001289139.2; = p.N71D on NM_001252507.3) | Missense Mutation (SNP) | VAF 18/322 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCDC40 | c.210G>C p.E70D | Missense Mutation (SNP) | VAF 27/180 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- CDIN1 | c.562G>T p.A188S (on ENST00000437989; = p.A90S on NM_032499.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/99 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.173); called by muse, mutect2
- CFAP47 | c.5285A>G p.N1762S | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated (0.4); PolyPhen benign (0.147); called by muse, mutect2
- CNGA2 | c.1691C>A p.P564H | Missense Mutation (SNP) | VAF 29/175 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSMD3 | c.962dup p.N321Kfs*19 | Frame Shift Ins (INS) | VAF 21/169 reads (12%) | called by mutect2, pindel, varscan2
- CSTF2 | c.646G>T p.G216* | Nonsense Mutation (SNP) | VAF 14/215 reads (7%) | called by muse, mutect2
- CSTF2T | c.1265C>T p.A422V | Missense Mutation (SNP) | VAF 8/198 reads (4%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.186); called by muse, mutect2
- CTCF | c.1138C>T p.Q380* | Nonsense Mutation (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2, varscan2
- CTNND1 | c.1179dup p.C394Mfs*5 | Frame Shift Ins (INS) | VAF 52/432 reads (12%) | called by mutect2, pindel, varscan2
- DGKG | c.1148G>A p.C383Y | Missense Mutation (SNP) | VAF 12/363 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DLGAP3 | c.1176G>A p.M392I | Missense Mutation (SNP) | VAF 20/440 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2
- DOCK5 | c.4484T>C p.F1495S | Missense Mutation (SNP) | VAF 14/244 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.723); called by muse, mutect2
- ELAVL2 | c.1069C>A p.H357N | Missense Mutation (SNP) | VAF 15/92 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ERCC3 | c.1627G>A p.A543T | Missense Mutation (SNP) | VAF 24/445 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.045); called by muse, mutect2
- EVI5 | c.2407A>G p.R803G | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.007); called by muse, mutect2
- FCRLA | c.1147T>A p.*383Kext*2 (on ENST00000367959; = p.*360Kext*2 on NM_032738.4) | Nonstop Mutation (SNP) | VAF 18/74 reads (24%) | called by muse, varscan2
- FLNB | c.2848A>G p.N950D | Missense Mutation (SNP) | VAF 16/288 reads (6%) | SIFT tolerated (0.8); PolyPhen benign (0.028); called by muse, mutect2
- HNRNPU | c.35A>T p.K12M | Missense Mutation (SNP) | VAF 90/496 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IGSF9B | c.172T>C p.Y58H | Missense Mutation (SNP) | VAF 32/167 reads (19%) | SIFT tolerated (0.29); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- INPPL1 | c.2927del p.P976Hfs*155 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel, varscan2
- JAM2 | c.293del p.N98Mfs*2 | Frame Shift Del (DEL) | VAF 16/147 reads (11%) | called by mutect2, pindel, varscan2
- KCNQ3 | c.2347A>G p.T783A | Missense Mutation (SNP) | VAF 21/322 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.306); called by muse, mutect2
- KDM5C | c.2239C>A p.L747M | Missense Mutation (SNP) | VAF 20/612 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- KMT2A | c.1205A>G p.Q402R | Missense Mutation (SNP) | VAF 13/120 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- KRT81 | c.709G>T p.D237Y | Missense Mutation (SNP) | VAF 120/671 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- LAMA2 | c.3917T>C p.M1306T | Missense Mutation (SNP) | VAF 70/386 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- LPIN2 | c.1250C>T p.A417V | Missense Mutation (SNP) | VAF 46/263 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MACF1 | c.5381C>T p.A1794V | Missense Mutation (SNP) | VAF 8/195 reads (4%) | called by muse, mutect2
- MED12 | c.4683_4685del p.L1562del | In Frame Del (DEL) | VAF 38/278 reads (14%) | called by pindel, varscan2
- MYT1 | c.3268T>C p.Y1090H | Missense Mutation (SNP) | VAF 13/197 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NARS1 | c.1025G>A p.C342Y | Missense Mutation (SNP) | VAF 7/169 reads (4%) | SIFT tolerated (0.05); PolyPhen benign (0.155); called by muse, mutect2
- NUP210 | c.3089T>C p.L1030S | Missense Mutation (SNP) | VAF 9/132 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); called by muse, mutect2
- NUP58 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- P4HA3 | c.11G>A p.G4E | Missense Mutation (SNP) | VAF 45/237 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRAMEF2 | c.596T>C p.L199S | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PRPSAP1 | c.347C>T p.A116V | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- RIC1 | c.4102G>A p.E1368K | Missense Mutation (SNP) | VAF 25/220 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RPRD1B | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SEC61A1 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 14/379 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.003); called by muse, mutect2
- SGCZ | c.464T>C p.V155A | Missense Mutation (SNP) | VAF 20/312 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- SIN3B | c.856del p.M286* | Frame Shift Del (DEL) | VAF 13/88 reads (15%) | called by mutect2, pindel, varscan2
- SKOR2 | c.1829G>T p.G610V | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT tolerated, low confidence (0.17); PolyPhen probably damaging (0.98); called by muse, varscan2
- SKOR2 | c.1828G>T p.G610W | Missense Mutation (SNP) | VAF 40/226 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); called by muse, varscan2
- SLC19A2 | c.406G>A p.A136T | Missense Mutation (SNP) | VAF 20/604 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SLC38A5 | c.1078dup p.A360Gfs*69 | Frame Shift Ins (INS) | VAF 8/65 reads (12%) | called by mutect2, pindel
- SLITRK2 | c.181del p.Q61Sfs*14 | Frame Shift Del (DEL) | VAF 29/163 reads (18%) | called by mutect2, pindel, varscan2
- SLURP1 | c.235G>A p.A79T | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.576); called by muse, mutect2
- SOCS7 | c.446G>A p.C149Y | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.558); called by muse, mutect2
- SZT2 | c.7741T>C p.L2581= (on ENST00000634258 / NM_001365999.1; = p.L2524= on NM_015284.4) | Splice Region (SNP) | VAF 12/104 reads (12%) | called by muse, mutect2
- TACC2 | c.2609C>A p.A870E | Missense Mutation (SNP) | VAF 48/316 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- UNC13A | c.624C>A p.S208R | Missense Mutation (SNP) | VAF 87/505 reads (17%) | SIFT tolerated, low confidence (0.09); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- USP19 | c.1145del p.G382Afs*35 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | called by mutect2, pindel
- VSIR | c.171G>T p.L57F | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.642); called by muse, mutect2
- WFS1 | c.1879del p.L627* | Frame Shift Del (DEL) | VAF 17/159 reads (11%) | called by mutect2, pindel, varscan2
- ZNF385A | c.566del p.G189Vfs*22 (on ENST00000338010 / NM_001130967.3; = p.G169Vfs*22 on NM_015481.3) | Frame Shift Del (DEL) | VAF 16/109 reads (15%) | called by mutect2, pindel, varscan2
- ZNF699 | c.236C>T p.T79I | Missense Mutation (SNP) | VAF 26/211 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- ACADVL | c.1377G>A p.R459= | Silent (SNP) | VAF 100/556 reads (18%) | called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.30C>T p.T10= | Silent (SNP) | VAF 24/121 reads (20%) | called by muse, mutect2, varscan2
- ARMCX2 | c.807G>A p.P269= | Silent (SNP) | VAF 63/394 reads (16%) | catalogued as rs782805456, COSV57531631; called by muse, mutect2, varscan2
- ASPHD2 | c.177C>T p.T59= | Silent (SNP) | VAF 35/190 reads (18%) | catalogued as rs150485615; called by muse, mutect2, varscan2
- ATP8B1 | c.2988C>T p.P996= | Silent (SNP) | VAF 98/540 reads (18%) | catalogued as rs776385207; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- BRF1 | c.327C>T p.T109= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as rs985720580; called by muse, mutect2
- CNPY2 | c.43C>T p.L15= | Silent (SNP) | VAF 54/313 reads (17%) | catalogued as rs1294202649; called by muse, mutect2, varscan2
- CYB5R3 | c.108C>T p.L36= | Silent (SNP) | VAF 108/620 reads (17%) | catalogued as rs11541432, COSV61545325; called by muse, mutect2, varscan2
- ELAVL2 | c.1068G>A p.T356= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as rs372576559; called by muse, mutect2, varscan2
- FASTKD3 | c.990T>C p.T330= | Silent (SNP) | VAF 44/228 reads (19%) | called by muse, mutect2, varscan2
- FNIP2 | c.1440G>A p.P480= | Silent (SNP) | VAF 16/204 reads (8%) | catalogued as rs761330575; called by muse, mutect2
- FZD5 | c.1146C>T p.D382= | Silent (SNP) | VAF 21/292 reads (7%) | catalogued as rs1462727173; called by muse, mutect2
- GAK | c.3336G>A p.T1112= | Silent (SNP) | VAF 17/117 reads (15%) | catalogued as rs1327406048; called by muse, mutect2, varscan2
- GPATCH8 | c.3600C>T p.G1200= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2
- HCFC1 | c.3987C>T p.T1329= | Silent (SNP) | VAF 14/296 reads (5%) | catalogued as rs370113081; called by muse, mutect2
- IGKV1-8 | c.135G>A p.A45= | Silent (SNP) | VAF 73/473 reads (15%) | catalogued as rs763160657; called by muse, mutect2, varscan2
- IL15RA | c.711C>T p.A237= | Silent (SNP) | VAF 18/358 reads (5%) | called by muse, mutect2
- IL20RA | c.1581A>G p.P527= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- ITGA8 | c.582G>A p.P194= | Silent (SNP) | VAF 17/152 reads (11%) | catalogued as rs778742435, COSV65233607; called by muse, mutect2, varscan2
- MCF2L2 | c.195G>A p.T65= | Silent (SNP) | VAF 33/215 reads (15%) | catalogued as rs772403994, COSV100192690, COSV61057086; called by muse, mutect2, varscan2
- METTL21A | c.429T>C p.A143= | Silent (SNP) | VAF 28/123 reads (23%) | called by muse, mutect2, varscan2
- MST1 | c.807T>C p.D269= | Silent (SNP) | VAF 46/539 reads (9%) | called by muse, varscan2
- MYO1C | c.3072G>A p.T1024= (on ENST00000648651 / NM_001080779.2; = p.T989= on NM_033375.5) | Silent (SNP) | VAF 70/290 reads (24%) | catalogued as rs775198165; called by muse, mutect2, varscan2
- OMA1 | c.954T>C p.I318= | Silent (SNP) | VAF 31/129 reads (24%) | called by muse, mutect2, varscan2
- PANX2 | c.282C>T p.Y94= | Silent (SNP) | VAF 27/146 reads (18%) | called by muse, mutect2, varscan2
- PAPSS2 | c.1365A>G p.L455= | Silent (SNP) | VAF 24/632 reads (4%) | called by muse, mutect2
- PCDH17 | c.2334C>T p.N778= | Silent (SNP) | VAF 55/440 reads (13%) | catalogued as rs771837972; called by muse, mutect2, varscan2
- PCNT | c.5283C>T p.H1761= | Silent (SNP) | VAF 31/488 reads (6%) | catalogued as rs763259541; called by muse, mutect2
- PLEC | c.6942G>A p.T2314= (on ENST00000322810 / NM_201380.4; = p.T2204= on NM_000445.5) | Silent (SNP) | VAF 116/912 reads (13%) | catalogued as rs782621816; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- POLR2D | c.36C>T p.D12= | Silent (SNP) | VAF 12/312 reads (4%) | called by muse, mutect2
- PRDM16 | c.687G>A p.T229= | Silent (SNP) | VAF 17/146 reads (12%) | catalogued as rs773103874, COSV54586597; called by muse, mutect2, varscan2
- RBMXL2 | c.702G>A p.S234= | Silent (SNP) | VAF 25/140 reads (18%) | catalogued as rs1190794791, COSV60978927; called by muse, mutect2, varscan2
- RPL21 | c.291G>A p.K97= | Silent (SNP) | VAF 22/354 reads (6%) | called by muse, mutect2
- RSPO3 | c.723C>T p.S241= | Silent (SNP) | VAF 36/204 reads (18%) | called by muse, mutect2, varscan2
- SFXN5 | c.897C>T p.F299= | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as rs567169280, COSV55586820; called by muse, mutect2, varscan2
- SLC18A3 | c.828G>A p.L276= | Silent (SNP) | VAF 57/280 reads (20%) | catalogued as COSV60322567; called by muse, mutect2, varscan2
- SLC25A48 | c.717C>T p.V239= (on ENST00000650267; = p.V185= on NM_001349335.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/84 reads (13%) | catalogued as rs551720758; called by muse, mutect2, varscan2
- SPATS1 | c.72C>T p.C24= | Silent (SNP) | VAF 67/372 reads (18%) | catalogued as COSV99913722; called by muse, mutect2, varscan2
- SULF1 | c.867G>T p.V289= | Silent (SNP) | VAF 12/85 reads (14%) | catalogued as COSV52692387; called by muse, mutect2, varscan2
- TRPA1 | c.87G>A p.T29= | Silent (SNP) | VAF 85/469 reads (18%) | catalogued as rs781262729, COSV51567279; called by muse, mutect2, varscan2
- USP10 | c.996C>T p.G332= | Silent (SNP) | VAF 41/234 reads (18%) | called by muse, mutect2, varscan2
- VPS28 | c.531C>T p.R177= | Silent (SNP) | VAF 14/58 reads (24%) | called by muse, mutect2
- VWC2L | c.435T>C p.V145= | Silent (SNP) | VAF 27/177 reads (15%) | called by muse, mutect2, varscan2
- WDR6 | c.3312C>T p.G1104= | Silent (SNP) | VAF 55/284 reads (19%) | called by muse, mutect2, varscan2
- YLPM1 | c.3324C>T p.S1108= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV53112959; called by muse, mutect2, varscan2
- ZRANB2 | c.651A>G p.S217= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as rs761117712; called by mutect2, varscan2
- AC073621.1 | n.484C>T | RNA (SNP) | VAF 19/114 reads (17%) | catalogued as rs1344034212; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852045 G>A | 3'Flank (SNP) | VAF 135/664 reads (20%) | catalogued as rs779720935; called by muse, mutect2, varscan2
- ANKRD33 | c.-6+104C>T | Intron (SNP) | VAF 12/74 reads (16%) | called by muse, mutect2, varscan2
- BHLHE22 | chr8:64576258 C>T | 5'Flank (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- C7orf65 | n.309G>A | RNA (SNP) | VAF 71/415 reads (17%) | called by muse, mutect2, varscan2
- CABP1 | c.655-3623G>A | Intron (SNP) | VAF 14/49 reads (29%) | catalogued as rs1488321914, COSV56459529; called by muse, mutect2, varscan2
- CCSER2 | c.*532del | 3'UTR (DEL) | VAF 36/219 reads (16%) | called by mutect2, pindel, varscan2
- CIB4 | c.187-10245A>G | Intron (SNP) | VAF 21/229 reads (9%) | called by muse, mutect2
- CXCL12 | c.*438T>C | 3'UTR (SNP) | VAF 41/185 reads (22%) | called by muse, mutect2, varscan2
- DTNBP1 | c.811+186C>T | Intron (SNP) | VAF 28/362 reads (8%) | catalogued as rs539657273, COSV59042914; called by muse, mutect2
- GCNT2 | c.925+26934A>G | Intron (SNP) | VAF 20/396 reads (5%) | catalogued as rs758903818; called by muse, mutect2
- GIPC1 | c.656-36C>T | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2
- HNRNPLL | c.803-416T>G | Intron (SNP) | VAF 18/100 reads (18%) | called by muse, mutect2, varscan2
- INTS11 | c.29-834C>T | Intron (SNP) | VAF 4/30 reads (13%) | catalogued as rs772397401, COSV100027955; called by mutect2, varscan2
- LARP1B | c.988+62C>T | Intron (SNP) | VAF 28/173 reads (16%) | catalogued as rs372146861; called by muse, mutect2, varscan2
- MYO1F | c.637-77dup | Intron (INS) | VAF 46/300 reads (15%) | called by mutect2, pindel, varscan2
- NUTM1 | c.-17T>C | 5'UTR (SNP) | VAF 34/217 reads (16%) | catalogued as COSV60995808; called by muse, mutect2, varscan2
- PABPC1P2 | n.531C>G | RNA (SNP) | VAF 51/238 reads (21%) | called by muse, mutect2, varscan2
- PLAUR | chr19:43646522 G>A | 3'Flank (SNP) | VAF 43/307 reads (14%) | called by muse, mutect2, varscan2
- PNPLA2 | c.758-47C>A | Intron (SNP) | VAF 64/266 reads (24%) | called by muse, mutect2, varscan2
- RASGRF1 | c.277-19T>G | Intron (SNP) | VAF 7/148 reads (5%) | called by muse, mutect2
- ST3GAL3 | c.254+9956C>T | Intron (SNP) | VAF 46/305 reads (15%) | called by muse, mutect2, varscan2
- SYCE1 | chr10:133567920 C>T | 5'Flank (SNP) | VAF 15/83 reads (18%) | catalogued as rs547329508; called by muse, mutect2, varscan2
- SYTL2 | c.1460-3208del | Intron (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel, varscan2
- TAZ | c.*434G>A | 3'UTR (SNP) | VAF 88/479 reads (18%) | catalogued as rs1369468549; called by muse, mutect2, varscan2
- TEX15 | chr8:30849221 C>T | 5'Flank (SNP) | VAF 14/132 reads (11%) | called by muse, mutect2, varscan2
- TM4SF4 | c.*16T>C | 3'UTR (SNP) | VAF 13/290 reads (4%) | called by muse, mutect2
- UBBP4 | n.844G>C | RNA (SNP) | VAF 158/790 reads (20%) | called by muse, varscan2
- UGT2B27P | n.34A>C | RNA (SNP) | VAF 41/245 reads (17%) | called by muse, mutect2, varscan2
